Somatic mutation profile of tumor specimen TARGET-15-SJMPAL046471-09A.2 (aliquot TARGET-15-SJMPAL046471-09A.2-01D) from TARGET case TARGET-15-SJMPAL046471, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (730 days).
Specimen TARGET-15-SJMPAL046471-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 492b5533-b4d3-46ec-99d7-9842d3424804.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL046471-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL046471-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88898f14-175a-473f-af61-48bd4fc0edfe

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK3 | c.1970G>A p.R657Q | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs758959409, COSV71685371; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RAB19 | c.583G>A p.G195S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs144362151; called by muse, mutect2, varscan2
- AKAP12 | c.285C>A p.N95K | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAPBPL | c.875C>A p.A292D | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.026); called by muse, mutect2
- KDM3B | c.2634C>A p.G878= | Silent (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- DNASE1L3 | c.801+27G>T | Intron (SNP) | VAF 4/39 reads (10%) | catalogued as COSV59156145; called by muse, mutect2, varscan2
- PDE7B | c.711+139C>A | Intron (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
